Gene-level copy-number profile of tumor specimen TCGA-DX-AB37-01A from TCGA case TCGA-DX-AB37, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Dedifferentiated liposarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 73.1 years (26,696 days).
Specimen TCGA-DX-AB37-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.e277fbd0-1c14-40a7-b3b3-aa3b2cd07e01.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DX-AB37-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/fb6280b3-f032-4360-972e-f998672f0e49

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 4,547; copy number 2: 44,647; copy number 3: 8,685; copy number 4: 1,299; copy number 5: 88; copy number 6: 62; copy number 7: 125; copy number 8: 24; copy number 9: 15; copy number 10: 42; copy number 11: 84; copy number 12: 49; copy number 13: 3; copy number 15: 1; copy number 16: 19; copy number 18: 26; copy number 21: 2; copy number 22: 1; copy number 23: 16; copy number 27: 14; copy number 28: 16; copy number 36: 51.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DX-AB37-01A-11D-A416-01): tumor purity 0.57, ploidy 2.16, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 638 genes in 31 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:67,522,299–67,561,446, 3 genes, copy number 6: LINC01702, RNU6-1031P, AL590559.1.
- chr3:8,775,402–8,963,773, 3 genes, copy number 9 (within-gene range 2–9): RAD18, AC034186.2, AC034186.1.
- chr3:9,014,123–9,015,979, 1 gene, copy number 9: SRGAP3-AS1.
- chr3:84,881,984–86,362,474, 11 genes, copy number 5–22: LINC02025, AC132660.2, CADM2, MIR5688, CADM2-AS2, CADM2-AS1, THAP12P2, AC107024.1, RNU6-1129P, AC108733.1, RN7SKP284.
- chr3:86,816,740–87,993,787, 14 genes, copy number 27: AC108706.1, VGLL3, PPATP1, LINC00506, MIR4795, CHMP2B, POU1F1, KRT8P25, APOOP2, PSMC1P6, AC108749.1, RNU6-873P, HTR1F, RNU6ATAC6P.
- chr3:89,107,621–94,507,620, 21 genes, copy number 7–18 (within-gene range 2–18): EPHA3, AC109129.1, MTCO2P6, MTCO1P6, U3, RNU6-712P, PROS2P, HSPE1P19, ABBA01000933.1, ABBA01000935.2, RNU6-488P, PROS1, Y_RNA, RNU6-511P, ARL13B, HMGN1P7, STX19, DHFR2, NSUN3, RBBP4P2, ARMC10P1.
- chr3:100,363,431–103,241,230, 44 genes, copy number 8–12 (within-gene range 3–12): TOMM70, LNP1, TMEM45A, ADGRG7, AC069223.1, GMFBP1, TFG, ABI3BP, AC080014.1, RNU6-865P, ACTR3P3, IMPG2, SENP7, ZNF90P1, AC110994.1, AC110994.2, Y_RNA, FAM172BP, TRMT10C, PCNP, AC073861.1, AC084198.1, RNU6-1256P, Y_RNA, Y_RNA, ZBTB11, RNY1P12, ZBTB11-AS1, RPL24, AC084198.2, PDCL3P4, CEP97, NXPE3, AC020651.1, NFKBIZ, AC020651.2, LINC02085, Y_RNA, AC106712.1, ZPLD1, AC063938.1, RNU6-461P, RNU1-43P, NDUFA4P2.
- chr3:122,660,613–128,825,942, 146 genes, copy number 6–7 (broad region; genes not listed).
- chr3:137,771,660–141,818,490, 80 genes, copy number 11 (broad region; genes not listed).
- chr3:143,620,528–143,856,142, 2 genes, copy number 11: AC073358.1, AC107421.1.
- chr3:147,386,046–147,510,293, 3 genes, copy number 7: ZIC4, ZIC4-AS1, ZIC1.
- chr7:112,953,282–113,146,330, 5 genes, copy number 8: HRAT17, AC073346.2, GPR85, AC073346.1, SMIM30.
- chr9:14,586,766–15,544,294, 23 genes, copy number 5: AL159169.3, AL159169.2, CDCA4P1, ZDHHC21, CER1, FREM1, AL512643.2, AL512643.1, RNU6-1260P, CLCN3P1, LDHAP4, AL592293.1, PSIP1P1, RNU6-559P, TTC39B, RPL7P33, SNAPC3, RNU6-319P, PSIP1, AL513423.1, RN7SL98P, FTH1P12, RNU6-246P.
- chr9:15,588,355–15,776,286, 2 genes, copy number 5: HMGN2P16, RNU6-14P.
- chr12:51,815,043–51,852,729, 4 genes, copy number 10 (within-gene range 2–10): AC068987.2, FIGNL2, AC068987.3, FIGNL2-DT.
- chr12:58,872,149–59,586,943, 11 genes, copy number 6–16: LRIG3, AC068305.2, RPS6P22, AC068305.1, AC046129.1, AC108721.2, AC108721.1, RNU6-279P, RNU6-871P, LINC02448, RNU4-20P.
- chr12:63,558,913–64,162,217, 12 genes, copy number 6 (within-gene range 2–6): DPY19L2, AC084357.2, AC027667.1, AC084357.3, AC084357.1, RXYLT1, RXYLT1-AS1, PABPC1P4, SRGAP1, RPL36AP41, AC079866.2, AC079866.1.
- chr12:66,116,555–66,343,643, 11 genes, copy number 10: LLPH, AC078927.1, LLPH-DT, TMBIM4, IRAK3, RBMS1P1, MIR6502, AC078889.1, PDCL3P7, RN7SKP166, HELB.
- chr12:68,552,995–72,186,618, 77 genes, copy number 12–36 (within-gene range 3–36) (broad region; genes not listed).
- chr12:73,115,957–73,208,317, 3 genes, copy number 8: AC090503.2, LINC02444, AC090503.1.
- chr12:73,820,315–74,402,600, 1 gene, copy number 12 (within-gene range 2–12): LINC02882.
- chr12:74,039,024–74,728,851, 10 genes, copy number 12: LINC02394, AC090502.3, AC090502.2, AC090502.1, VENTXP3, ATXN7L3B, AC025257.1, AC123904.2, AC123904.1, AC123904.3.
- chr12:78,052,181–78,131,004, 2 genes, copy number 10: AC073571.1, PRXL2AP1.
- chr12:90,905,622–91,058,024, 4 genes, copy number 8 (within-gene range 3–8): CCER1, LINC00615, EPYC, KERA.
- chr12:91,140,484–91,193,942, 2 genes, copy number 21: DCN, AC007115.1.
- chr12:91,632,912–92,772,455, 20 genes, copy number 9–28 (within-gene range 3–28): AC126175.1, AC126175.2, AC025254.1, AC090049.2, LINC02404, AC090049.1, LINC01619, AC123512.1, AC025164.2, BTG1, AC025164.1, RPL21P106, Y_RNA, LINC02391, CLLU1-AS1, CLLU1, AC063949.2, LINC02397, AC063949.1, PLEKHG7.
- chr12:94,140,077–95,442,482, 34 genes, copy number 16–23: AC123567.1, PLXNC1, AC123567.2, AC073655.3, AC073655.1, AC073655.2, CEP83, RN7SL330P, RBMS2P1, CEP83-DT, AC023161.1, RN7SL483P, NSA2P2, SUCLG2P2, MIR5700, TMCC3, MIR7844, LSM3P2, KRT19P2, MIR492, NDUFA12, NR2C1, FGD6, AC126615.2, AC126615.1, VEZT, Y_RNA, CBX3P5, RNU6-808P, MIR331, MIR3685, AC084879.1, AC084879.2, RNU6-735P.
- chr17:9,021,510–11,242,062, 55 genes, copy number 5 (within-gene range 4–5): NTN1, AC005695.1, AC005695.3, STX8, AC005695.2, AC087501.1, AC087501.2, AC087501.3, AC087501.4, CFAP52, RPL19P18, AC118755.2, USP43, AC118755.1, AC027045.2, DHRS7C, AC027045.1, GSG1L2, AC027045.3, GLP2R, NPM1P45, RCVRN, GAS7, RPS27AP1, AC005291.2, MYH13, AC005291.1, AC005323.2, MYHAS, MYH8, MYH4, MYH1, MYH2, AC005323.1, MYH3, AC002347.1, SCO1, AC002347.2, ADPRM, TMEM220, MAGOH2P, TMEM220-AS1, AC015908.7, AC015908.3, AC015908.1, AC015908.4, AC015908.6, TMEM238L, AC015908.5, PIRT, AC015908.2, RNU6-1065P, RPL15P21, RN7SL601P, AC005548.1.
- chr17:11,288,205–11,290,811, 1 gene, copy number 5: AC005725.1.
- chr19:647,526–998,438, 25 genes, copy number 10: RNF126, AC004156.1, FSTL3, PRSS57, RPS2P52, PALM, MISP, AC006273.1, LINC01836, PTBP1, MIR4745, PLPPR3, MIR3187, AZU1, PRTN3, ELANE, CFD, MED16, RNU6-9, R3HDM4, KISS1R, ARID3A, AC005379.1, AC005391.1, WDR18.
- chr19:42,580,243–42,855,691, 8 genes, copy number 9 (within-gene range 2–9): CEACAM8, CEACAMP1, CEACAMP5, RPS10P28, PSG3, PSG8, CEACAMP6, PSG8-AS1.

Autosomal genes at a single copy (total copy number 1): 4,547. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
